Gene-level copy-number profile of tumor specimen TCGA-L5-A8NJ-01A from TCGA case TCGA-L5-A8NJ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: GX; Age at diagnosis: 77.2 years (28,200 days).
Specimen TCGA-L5-A8NJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.221d3836-d867-4458-a7f3-108a3b374f77.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A8NJ-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/edd1ed69-5095-44ff-a075-2e5593798a8e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 1,188; copy number 2: 22,210; copy number 3: 24,124; copy number 4: 11,534; copy number 5: 494; copy number 6: 67; copy number 8: 53; copy number 9: 58; copy number 16: 33; copy number 20: 41.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A8NJ-01A-11D-A36I-01): tumor purity 0.85, ploidy 2.81, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,128,103, 13 genes (within-gene range 0–2): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.
- chr21:34,836,286–34,884,882, 1 gene: AP000331.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 185 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:37,828,305–40,100,589, 99 genes, copy number 9–20 (within-gene range 2–20) (broad region; genes not listed).
- chr17:40,921,430–41,966,503, 86 genes, copy number 8–16 (within-gene range 3–16) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,188. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
